Somatic mutation profile of tumor specimen ALCH-AEKD-TTP1-A (aliquot ALCH-AEKD-TTP1-A-1-0-D-A618-36) from ALCHEMIST case ALCH-AEKD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 66.3 years (24,223 days).
Specimen ALCH-AEKD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d8069e0-ee8b-4405-88f0-bc49fe1aedb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEKD-NB1-A (Blood Derived Normal), aliquot ALCH-AEKD-NB1-A-1-0-D-A618-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7b61460-2731-43f8-83fc-2a5bd22c508e

The open-access MAF lists 327 somatic variants for this specimen: 230 protein-altering or splice-affecting, 50 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 205, Silent 50, Intron 21, Nonsense Mutation 15, RNA 10, 5'Flank 6, 3'UTR 6, Frame Shift Del 5, 5'UTR 4, Splice Site 3, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 115/458 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 94/428 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRB1 | c.1663G>A p.G555R | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs549410622; called by mutect2, varscan2
- ADGRB3 | c.908G>A p.C303Y | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65408442; called by muse, mutect2, varscan2
- APOB | c.10588G>A p.V3530M | Missense Mutation (SNP) | VAF 66/350 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.882); catalogued as rs200184366; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B4 | c.2195G>T p.R732L | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as COSV100396943; called by muse, mutect2, varscan2
- CABS1 | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.013); catalogued as rs767742817; called by muse, mutect2, varscan2
- CALN1 | c.334G>T p.D112Y (on ENST00000329008 / NM_001017440.3; = p.D154Y on NM_031468.4) | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV61121606; called by muse, mutect2, varscan2
- CCDC39 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs377703572; called by muse, mutect2, varscan2
- CCKBR | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs1171410975; called by muse, mutect2, varscan2
- CPO | c.739G>T p.G247C | Missense Mutation (SNP) | VAF 62/278 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55940433; called by mutect2, varscan2
- CSMD3 | c.2459G>T p.R820L (on ENST00000297405 / NM_001363185.1; = p.R716L on NM_052900.3) | Missense Mutation (SNP) | VAF 36/278 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52328384; called by muse, mutect2, varscan2
- CUL3 | c.200A>T p.H67L | Missense Mutation (SNP) | VAF 67/264 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV52369257; called by muse, mutect2, varscan2
- DCAF7 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 40/153 reads (26%) | catalogued as COSV60408044; called by muse, mutect2, varscan2
- DLGAP1 | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs201740434; called by muse, mutect2, varscan2
- DLGAP2 | c.239G>T p.S80I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.167); catalogued as rs771346886; called by muse, mutect2, varscan2
- FAM135B | c.2819C>A p.T940K | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV52708278, COSV99421433; called by muse, mutect2, varscan2
- FCRL3 | c.940G>T p.G314C | Missense Mutation (SNP) | VAF 64/342 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1299239406; called by muse, mutect2, varscan2
- GDF7 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1316439911, COSV55347685, COSV99694109; called by muse, mutect2
- GK2 | c.138G>T p.E46D | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs201184235, COSV62626071; called by muse, mutect2, varscan2
- GRID1 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 34/382 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV100025305; called by muse, mutect2
- GRIN3A | c.1027A>T p.T343S | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV62454331; called by muse, mutect2, varscan2
- HGF | c.2083C>A p.R695S | Missense Mutation (SNP) | VAF 66/399 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55944955; called by muse, mutect2, varscan2
- HGFAC | c.1664G>A p.R555Q | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs771440155; called by muse, mutect2, varscan2
- HHLA1 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs118152489; called by muse, mutect2
- IGHV3-23 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 13/318 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); catalogued as rs782335212; called by muse, mutect2
- ITGA9 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 90/412 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs749882984, COSV53240748; called by mutect2, varscan2
- KHDC1 | c.484G>T p.G162W (on ENST00000370384 / NM_001251874.2; = p.G89W on NM_030568.5) | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100001821; called by muse, mutect2, varscan2
- KIAA1109 | c.4241C>T p.P1414L | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.998); catalogued as COSV52679677; called by muse, mutect2, varscan2
- KNCN | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 56/385 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1010532339; called by muse, mutect2, varscan2
- LAMA1 | c.4613G>A p.R1538Q | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs773861728; called by muse, mutect2, varscan2
- LIFR | c.1510C>G p.L504V | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs768265879; called by muse, mutect2, varscan2
- MAGEE1 | c.1540G>T p.E514* | Nonsense Mutation (SNP) | VAF 36/385 reads (9%) | catalogued as COSV63910532; called by muse, mutect2
- MAN2A2 | c.3374C>T p.P1125L | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as rs758780669; called by muse, mutect2, varscan2
- MAPK10 | c.788G>A p.R263Q (on ENST00000359221 / NM_001351625.2; = p.R301Q on NM_002753.5) | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.285); catalogued as COSV100174734, COSV60380081; called by muse, mutect2, varscan2
- MEOX2 | c.763C>G p.R255G | Missense Mutation (SNP) | VAF 71/570 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV56287712; called by muse, mutect2, varscan2
- MPPED2 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as rs200641482, COSV63897814; called by muse, mutect2, varscan2
- MUC5B | c.10607C>T p.T3536I | Missense Mutation (SNP) | VAF 92/434 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); catalogued as rs747078317; called by muse, mutect2, varscan2
- MYH7 | c.1670T>A p.L557Q | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV62522087; called by muse, mutect2, varscan2
- NAAA | c.1030G>T p.G344C | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV54433644; called by muse, mutect2, varscan2
- NEK8 | c.1183C>T p.H395Y | Missense Mutation (SNP) | VAF 42/480 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.454); catalogued as rs763610690; called by muse, mutect2
- NOS2 | c.1698C>G p.N566K | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV58224276; called by muse, mutect2, varscan2
- OR2T34 | c.429G>T p.Q143H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100170208; called by mutect2, varscan2
- PCDH17 | c.856G>T p.V286L | Missense Mutation (SNP) | VAF 62/361 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.341); catalogued as COSV100931464; called by muse, mutect2, varscan2
- PCDHGB1 | c.671A>G p.H224R | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1243075906; called by muse, mutect2, varscan2
- PDGFRA | c.1027C>A p.P343T | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57272357; called by muse, mutect2, varscan2
- PKD1 | c.6631G>A p.V2211M | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.56); catalogued as rs1373324167; called by muse, mutect2, varscan2
- PNMA8A | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769607992; called by muse, mutect2, varscan2
- POLD3 | c.808G>T p.V270F | Missense Mutation (SNP) | VAF 50/318 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs747364670; called by muse, varscan2
- PRSS12 | c.1354G>T p.D452Y | Missense Mutation (SNP) | VAF 50/434 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs984022562; called by muse, varscan2
- RAB12 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 48/464 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100251531; called by muse, mutect2, varscan2
- RAB26 | c.83C>G p.P28R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.053); catalogued as rs1054134307; called by muse, mutect2, varscan2
- RAD51AP2 | c.2972T>C p.V991A | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.187); catalogued as rs1329493461; called by muse, varscan2
- RALBP1 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs1457796369; called by muse, mutect2, varscan2
- RELN | c.3182C>T p.P1061L | Missense Mutation (SNP) | VAF 53/427 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1465720097, COSV100634718; called by muse, mutect2, varscan2
- RFPL4B | c.616C>A p.R206S | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.392); catalogued as COSV101480717; called by muse, mutect2, varscan2
- RGS21 | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 67/307 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101313980; called by muse, mutect2, varscan2
- SAMD9 | c.1840A>G p.I614V | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.018); catalogued as rs770928576; called by muse, mutect2, varscan2
- SGIP1 | c.1789G>C p.G597R | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99392493; called by muse, mutect2, varscan2
- SLC27A1 | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 51/326 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs200011104, COSV53096950; called by muse, mutect2, varscan2
- SOX9 | c.1123C>T p.Q375* | Nonsense Mutation (SNP) | VAF 9/92 reads (10%) | catalogued as CM971410; called by muse, mutect2
- SPATA21 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs142328321; called by muse, mutect2, varscan2
- SULT4A1 | c.403C>A p.P135T | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50783972; called by muse, mutect2, varscan2
- TAAR5 | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57798679, COSV57799526; called by muse, mutect2, varscan2
- TBX20 | c.556C>T p.H186Y | Missense Mutation (SNP) | VAF 42/470 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM088571; called by muse, mutect2
- TG | c.1021G>C p.A341P | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.858); catalogued as rs759789389, COSV99600793; called by muse, mutect2, varscan2
- TGFBR2 | c.1279C>A p.P427T | Missense Mutation (SNP) | VAF 62/574 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM064333, COSV55458379; called by muse, mutect2
- TMEM132A | c.1190G>A p.R397K (on ENST00000453848 / NM_178031.3; = p.R398K on NM_017870.4) | Missense Mutation (SNP) | VAF 53/436 reads (12%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.987); catalogued as rs59336122; called by muse, mutect2, varscan2
- TMEM31 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 76/508 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.646); catalogued as rs777807891, COSV100129064; called by muse, mutect2, varscan2
- TMEM74 | c.899C>A p.A300E | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV52463296; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3082T>C p.F1028L | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100836203; called by muse, mutect2
- TRPV5 | c.1244A>G p.Y415C | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1339841458; called by muse, mutect2, varscan2
- TSEN2 | c.628G>C p.V210L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV53189466, COSV53190565; called by muse, mutect2, varscan2
- TTC6 | c.970G>C p.V324L (on ENST00000267368; = p.V1690L on NM_001310135.3) | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs1334099504, COSV57446197; called by muse, mutect2, varscan2
- TTLL9 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs376433493; called by muse, mutect2, varscan2
- USH2A | c.7765C>G p.H2589D | Missense Mutation (SNP) | VAF 44/532 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0.096); catalogued as rs747492773, CM1410583; ClinVar: uncertain significance; called by muse, mutect2
- USP17L1 | c.1557C>A p.N519K | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.878); catalogued as rs754328396; called by muse, mutect2, varscan2
- VPS51 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as rs11548902; called by muse, mutect2, varscan2
- WDR41 | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1459214254; called by muse, mutect2, varscan2
- XKR3 | c.440G>T p.R147M | Missense Mutation (SNP) | VAF 56/485 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as rs766355071, COSV100509203, COSV58887539; called by muse, mutect2, varscan2
- ZAN | c.2904A>T p.K968N | Missense Mutation (SNP) | VAF 72/432 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.7); catalogued as rs776515794; called by muse, mutect2, varscan2
- ZNF470 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.757); catalogued as rs779256798; called by muse, mutect2, varscan2
- ZNF521 | c.2276G>T p.W759L | Missense Mutation (SNP) | VAF 51/430 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV64132193; called by muse, mutect2, varscan2
- ADCY9 | c.1915C>G p.P639A | Missense Mutation (SNP) | VAF 20/233 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2
- ADGRL3 | c.3892G>T p.G1298W | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ALAS2 | c.767C>A p.S256Y | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ALG8 | c.119A>C p.H40P | Missense Mutation (SNP) | VAF 69/585 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD20A1 | c.1690G>T p.E564* | Nonsense Mutation (SNP) | VAF 20/771 reads (3%) | called by muse, mutect2
- AP3B2 | c.1915C>T p.Q639* | Nonsense Mutation (SNP) | VAF 26/106 reads (25%) | called by muse, mutect2, varscan2
- APLF | c.1030C>A p.H344N | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.08); called by muse, mutect2
- APOB | c.1841_1844del p.L614* | Frame Shift Del (DEL) | VAF 20/262 reads (8%) | called by mutect2, pindel
- ASXL3 | c.3673A>T p.S1225C | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); called by muse, mutect2
- ATG2A | c.3952G>T p.G1318C | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by mutect2, varscan2
- ATP9B | c.2921C>G p.T974S | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- BEND2 | c.2060G>A p.S687N | Missense Mutation (SNP) | VAF 56/353 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- BPIFB4 | c.257A>T p.Q86L | Missense Mutation (SNP) | VAF 123/393 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- BPIFB6 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 85/261 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1B | c.4103C>A p.P1368H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CACNA1S | c.4978A>T p.N1660Y | Missense Mutation (SNP) | VAF 92/301 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- CACNG6 | c.370del p.E124Rfs*14 | Frame Shift Del (DEL) | VAF 27/169 reads (16%) | called by mutect2, pindel, varscan2
- CDH5 | c.1471G>T p.A491S | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.964); called by muse, mutect2
- CDK13 | c.1447G>T p.A483S | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CEL | c.828G>C p.R276S (on ENST00000673714; = p.R273S on NM_001807.6) | Missense Mutation (SNP) | VAF 42/425 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CHST13 | c.548C>A p.A183D | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLCA2 | c.80C>A p.P27Q | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- CNOT2 | c.464C>A p.T155K | Missense Mutation (SNP) | VAF 62/235 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CNTNAP5 | c.3396C>G p.F1132L | Missense Mutation (SNP) | VAF 59/263 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- COL24A1 | c.2546G>T p.G849V | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPXCR1 | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 36/254 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DCDC1 | c.2353G>T p.V785L | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- DHX35 | c.16G>T p.G6* | Nonsense Mutation (SNP) | VAF 65/235 reads (28%) | called by muse, mutect2, varscan2
- DHX38 | c.653A>G p.E218G | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DIPK1C | c.745C>G p.Q249E | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.303); called by muse, mutect2
- DNMT3B | c.1250G>T p.R417L | Missense Mutation (SNP) | VAF 85/302 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- DOP1A | c.2545G>C p.A849P | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.883); called by muse, mutect2
- EGFLAM | c.1268T>A p.L423* | Nonsense Mutation (SNP) | VAF 37/370 reads (10%) | called by muse, mutect2, varscan2
- EMP1 | c.121T>C p.W41R | Missense Mutation (SNP) | VAF 60/270 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA8 | c.2983C>A p.L995M | Missense Mutation (SNP) | VAF 54/258 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ERN2 | c.1187C>A p.P396Q | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.097); called by muse, varscan2
- F13B | c.133T>C p.F45L | Missense Mutation (SNP) | VAF 45/304 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- FNDC3B | c.2033G>T p.R678M | Missense Mutation (SNP) | VAF 55/289 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- FOXO1 | c.1447G>T p.G483W | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- FRMPD4 | c.1261_1262del p.G421Pfs*44 | Frame Shift Del (DEL) | VAF 35/172 reads (20%) | called by mutect2, pindel, varscan2
- GABRG2 | c.616T>A p.L206M | Missense Mutation (SNP) | VAF 103/490 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GDF10 | c.608C>A p.A203D | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- GK2 | c.431C>A p.P144Q | Missense Mutation (SNP) | VAF 42/346 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GMIP | c.1593G>T p.E531D | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); called by muse, mutect2
- GPR15 | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 53/208 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- HAND2 | c.137G>T p.W46L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- HGSNAT | c.1292A>G p.Y431C | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- IGKV1-9 | c.294C>G p.S98R | Missense Mutation (SNP) | VAF 100/523 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- IGSF1 | c.3905C>A p.T1302N | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); called by muse, mutect2
- KCNV2 | c.1552G>A p.V518M | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- KIAA1217 | c.1012A>G p.M338V | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIRREL3 | c.1090C>A p.L364M | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- KRT40 | c.264T>A p.N88K | Missense Mutation (SNP) | VAF 78/520 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); called by muse, varscan2
- L3MBTL1 | c.2368G>T p.D790Y (on ENST00000418998 / NM_001377303.1; = p.D700Y on NM_015478.7) | Missense Mutation (SNP) | VAF 104/309 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LMBRD2 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 117/689 reads (17%) | called by muse, mutect2, varscan2
- LRRN3 | c.1518G>T p.L506F | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.944); called by muse, mutect2
- LYNX1 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- MAGEB6B | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MCAM | c.798C>A p.D266E | Missense Mutation (SNP) | VAF 31/364 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MISP | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MKS1 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 30/364 reads (8%) | called by muse, mutect2
- MS4A18 | c.842G>A p.R281K (on ENST00000398983; = p.R283K on NM_001354471.1) | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MS4A7 | c.627G>T p.Q209H | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- MUC16 | c.39816C>G p.Y13272* | Nonsense Mutation (SNP) | VAF 26/211 reads (12%) | called by muse, mutect2, varscan2
- MUC16 | c.30053C>A p.T10018N | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MUC5AC | c.1549C>A p.Q517K | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- MXRA5 | c.6883G>C p.G2295R | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYH7 | c.4875G>T p.M1625I | Missense Mutation (SNP) | VAF 93/435 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- MYOCD | c.81A>T p.R27S | Missense Mutation (SNP) | VAF 20/347 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NAP1L2 | c.1288G>T p.D430Y | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- NCR3 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NDUFB5 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- NEK1 | c.1411G>C p.G471R | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- NEK10 | c.3415-1G>C p.X1139_splice | Splice Site (SNP) | VAF 36/163 reads (22%) | called by muse, mutect2, varscan2
- NEK8 | c.1182G>T p.K394N | Missense Mutation (SNP) | VAF 42/476 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.216); called by muse, mutect2
- NLRP3 | c.2116C>A p.L706I | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- NPY2R | c.272A>G p.N91S | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NRXN1 | c.2278T>A p.S760T | Missense Mutation (SNP) | VAF 33/360 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- NTN1 | c.912del p.C304Wfs*126 | Frame Shift Del (DEL) | VAF 14/73 reads (19%) | called by mutect2, pindel, varscan2
- NUP93 | c.2119A>G p.I707V | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, varscan2
- OR14K1 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 38/464 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.085); called by muse, mutect2
- OR1S1 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 31/268 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- OR2L8 | c.644G>T p.C215F | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- OR2T33 | c.116G>C p.G39A | Missense Mutation (SNP) | VAF 48/444 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- OR51B6 | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 67/352 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR52K1 | c.652C>A p.L218M | Missense Mutation (SNP) | VAF 61/384 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5AP2 | c.381C>G p.D127E | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR5K1 | c.53C>A p.T18K | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- PAGE5 | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 54/327 reads (17%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- PAGE5 | c.308C>A p.P103H | Missense Mutation (SNP) | VAF 54/329 reads (16%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PARVB | c.581G>T p.R194M | Missense Mutation (SNP) | VAF 17/277 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2
- PAX5 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHGA4 | c.1486A>C p.N496H | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PFAS | c.3802G>T p.E1268* | Nonsense Mutation (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- PIK3R1 | c.2150C>T p.P717L (on ENST00000521381 / NM_181523.3; = p.P447L on NM_181504.4) | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIK3R5 | c.224A>G p.Y75C | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PLA2G4C | c.1609A>C p.S537R | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- PLCB2 | c.515A>T p.Q172L | Missense Mutation (SNP) | VAF 85/334 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PLPPR4 | c.1131C>A p.N377K | Missense Mutation (SNP) | VAF 39/368 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PNN | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 98/370 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- POSTN | c.283+2T>C p.X95_splice | Splice Site (SNP) | VAF 44/339 reads (13%) | called by muse, mutect2, varscan2
- PPP2R1B | c.964G>A p.G322S | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2
- PRSS38 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- PRUNE2 | c.4756C>A p.L1586I | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2
- PSD4 | c.2410A>C p.K804Q | Missense Mutation (SNP) | VAF 38/447 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- PTPRT | c.3236C>A p.P1079H | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM15B | c.2156A>T p.Q719L | Missense Mutation (SNP) | VAF 32/292 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM26 | c.2767G>C p.D923H (on ENST00000438737 / NM_001366735.2; = p.D896H on NM_022118.5) | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2
- RFPL4AL1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 50/468 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- RGS3 | c.1219G>T p.E407* (on ENST00000350696 / NM_001282923.2; = p.E295* on NM_017790.4) | Nonsense Mutation (SNP) | VAF 30/222 reads (14%) | called by muse, mutect2, varscan2
- SACS | c.9833G>T p.W3278L | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.787); called by muse, mutect2
- SACS | c.9832T>C p.W3278R | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- SAMD9 | c.4598G>T p.R1533L | Missense Mutation (SNP) | VAF 81/542 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- SETD1B | c.3703G>T p.D1235Y | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); called by mutect2, varscan2
- SHOX | c.749T>A p.I250N | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SLC25A13 | c.1946G>C p.G649A | Missense Mutation (SNP) | VAF 70/469 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC35A1 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 47/349 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SLC4A10 | c.926C>A p.P309H | Missense Mutation (SNP) | VAF 62/376 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLFN5 | c.581A>T p.H194L | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- SPATA31D1 | c.4331A>G p.N1444S | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPEF2 | c.981G>C p.E327D | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- SV2B | c.1561G>T p.E521* | Nonsense Mutation (SNP) | VAF 128/331 reads (39%) | called by mutect2, varscan2
- TAF3 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 26/514 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.265); called by muse, mutect2
- TBRG4 | c.780G>C p.K260N | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- TEX35 | c.230T>C p.M77T | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- TFDP2 | c.1153T>G p.S385A (on ENST00000489671 / NM_001178139.2; = p.S325A on NM_006286.5) | Missense Mutation (SNP) | VAF 21/246 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- THAP9 | c.685T>C p.Y229H | Missense Mutation (SNP) | VAF 40/394 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2
- TLN2 | c.1513A>T p.S505C | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TMTC1 | c.1128+2T>A p.X376_splice (on ENST00000539277 / NM_001193451.2; = p.X268_splice on NM_175861.3) | Splice Site (SNP) | VAF 9/57 reads (16%) | called by muse, varscan2
- TNR | c.3094A>G p.T1032A | Missense Mutation (SNP) | VAF 102/307 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TOPAZ1 | c.3686T>C p.V1229A | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, varscan2
- TRAV24 | c.133T>A p.C45S | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRBV4-2 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 63/347 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- TTC24 | c.242G>T p.C81F | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTC26 | c.1422G>T p.M474I | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TTC6 | c.179G>T p.C60F (on ENST00000267368; = p.C1329F on NM_001310135.3) | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TUBA3C | c.1079C>A p.P360H | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TUSC3 | c.744G>A p.W248* | Nonsense Mutation (SNP) | VAF 39/307 reads (13%) | called by muse, mutect2, varscan2
- VN1R2 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 64/269 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- WDFY4 | c.6513del p.W2171Cfs*5 | Frame Shift Del (DEL) | VAF 19/89 reads (21%) | called by mutect2, pindel, varscan2
- YTHDC2 | c.1042A>T p.S348C | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF135 | c.105G>T p.Q35H | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF582 | c.761C>A p.P254Q | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ZNF610 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 24/265 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); called by muse, mutect2
- ZNF772 | c.1133A>G p.Y378C | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZPBP | c.677T>G p.L226W | Missense Mutation (SNP) | VAF 54/317 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ZSWIM2 | c.1595G>A p.C532Y | Missense Mutation (SNP) | VAF 36/328 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACSM4 | c.759C>T p.C253= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as rs200562081; called by muse, mutect2, varscan2
- AL645922.1 | c.174C>T p.S58= | Silent (SNP) | VAF 103/395 reads (26%) | catalogued as rs753987052, COSV54960666; called by muse, mutect2, varscan2
- ANXA7 | c.186G>T p.A62= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as rs375225097; called by mutect2, varscan2
- ARNT | c.1386C>G p.T462= | Silent (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- ASXL3 | c.3156G>A p.R1052= | Silent (SNP) | VAF 33/302 reads (11%) | catalogued as rs1254700186, COSV52463066; called by muse, varscan2
- ASXL3 | c.3198C>A p.A1066= | Silent (SNP) | VAF 22/194 reads (11%) | catalogued as COSV99324377; called by muse, varscan2
- ATAD5 | c.5496A>G p.P1832= | Silent (SNP) | VAF 14/169 reads (8%) | called by muse, mutect2
- BMP5 | c.579G>T p.V193= | Silent (SNP) | VAF 80/347 reads (23%) | called by muse, mutect2, varscan2
- BTBD8 | c.3075G>T p.A1025= (on ENST00000636805 / NM_001376131.1; = p.A512= on NM_015237.4) | Silent (SNP) | VAF 67/405 reads (17%) | called by muse, mutect2, varscan2
- CASP8AP2 | c.3183A>T p.S1061= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV52749804; called by muse, mutect2, varscan2
- CATSPER1 | c.366T>C p.D122= | Silent (SNP) | VAF 47/284 reads (17%) | called by muse, mutect2, varscan2
- CCDC169 | c.636C>A p.L212= | Silent (SNP) | VAF 33/207 reads (16%) | called by muse, mutect2, varscan2
- CPVL | c.423C>A p.P141= | Silent (SNP) | VAF 58/332 reads (17%) | called by muse, mutect2, varscan2
- CPZ | c.1077G>T p.P359= (on ENST00000360986 / NM_001014447.3; = p.P348= on NM_003652.3) | Silent (SNP) | VAF 24/102 reads (24%) | called by muse, mutect2
- DSG3 | c.1287T>G p.R429= | Silent (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- EVX1 | c.180C>A p.R60= | Silent (SNP) | VAF 13/146 reads (9%) | called by muse, mutect2
- FAT3 | c.13623C>T p.L4541= | Silent (SNP) | VAF 18/278 reads (6%) | catalogued as rs758214772, COSV99969153; called by muse, mutect2
- GRID1 | c.1440T>C p.F480= | Silent (SNP) | VAF 31/271 reads (11%) | catalogued as COSV60037831; called by muse, mutect2, varscan2
- H3C8 | c.171G>A p.K57= | Silent (SNP) | VAF 59/253 reads (23%) | catalogued as rs1424415639; called by muse, mutect2, varscan2
- HIGD2B | c.267C>T p.T89= | Silent (SNP) | VAF 39/155 reads (25%) | catalogued as rs1466317470; called by muse, mutect2, varscan2
- HIVEP1 | c.1692G>C p.V564= | Silent (SNP) | VAF 63/301 reads (21%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.189G>T p.G63= | Silent (SNP) | VAF 24/264 reads (9%) | catalogued as rs112642180; called by muse, mutect2
- IL12RB2 | c.2496C>T p.F832= | Silent (SNP) | VAF 32/355 reads (9%) | catalogued as rs751237197; called by muse, mutect2
- INSL6 | c.375T>A p.L125= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- JPH3 | c.807T>A p.A269= | Silent (SNP) | VAF 29/212 reads (14%) | called by muse, mutect2, varscan2
- KCNH1 | c.1752G>A p.L584= (on ENST00000271751 / NM_172362.3; = p.L557= on NM_002238.4) | Silent (SNP) | VAF 20/192 reads (10%) | called by muse, mutect2, varscan2
- KCNK13 | c.516C>A p.P172= | Silent (SNP) | VAF 49/203 reads (24%) | catalogued as COSV56413247; called by muse, mutect2, varscan2
- LIMS2 | c.810G>T p.S270= (on ENST00000355119 / NM_001161403.3; = p.S294= on NM_017980.4) | Silent (SNP) | VAF 38/129 reads (29%) | called by muse, mutect2, varscan2
- MAD1L1 | c.633C>T p.L211= | Silent (SNP) | VAF 45/514 reads (9%) | called by muse, mutect2
- MMAA | c.1263T>C p.I421= | Silent (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2
- NPHP3 | c.120G>T p.L40= | Silent (SNP) | VAF 24/182 reads (13%) | called by muse, mutect2, varscan2
- NXPE4 | c.184T>C p.L62= | Silent (SNP) | VAF 80/431 reads (19%) | called by muse, mutect2, varscan2
- OR52K1 | c.651C>A p.I217= | Silent (SNP) | VAF 60/356 reads (17%) | catalogued as rs769996238; called by mutect2, varscan2
- PHGR1 | c.138C>A p.P46= | Silent (SNP) | VAF 19/87 reads (22%) | called by muse, varscan2
- PIK3CG | c.2217C>T p.I739= | Silent (SNP) | VAF 72/400 reads (18%) | catalogued as rs746522201, COSV63246581; called by muse, varscan2
- POM121L12 | c.768G>T p.L256= | Silent (SNP) | VAF 46/257 reads (18%) | called by muse, mutect2, varscan2
- PTPRS | c.5511G>T p.R1837= | Silent (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
- PTPRT | c.3237C>A p.P1079= | Silent (SNP) | VAF 22/74 reads (30%) | called by muse, varscan2
- RNF125 | c.687G>T p.S229= | Silent (SNP) | VAF 28/245 reads (11%) | called by muse, mutect2, varscan2
- SCART1 | c.1275G>T p.A425= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- SDR42E2 | c.546C>A p.I182= | Silent (SNP) | VAF 25/356 reads (7%) | called by muse, mutect2
- SLITRK5 | c.2058G>T p.V686= | Silent (SNP) | VAF 20/249 reads (8%) | called by muse, mutect2
- SPHK1 | c.600G>A p.L200= (on ENST00000392496 / NM_001355139.2; = p.L214= on NM_021972.4) | Silent (SNP) | VAF 22/173 reads (13%) | called by muse, mutect2, varscan2
- STK19 | c.720G>A p.Q240= (on ENST00000375333 / NM_032454.1; = p.Q236= on NM_004197.1) | Silent (SNP) | VAF 18/198 reads (9%) | catalogued as COSV64692243; called by muse, mutect2
- STOX1 | c.477A>G p.P159= | Silent (SNP) | VAF 12/203 reads (6%) | catalogued as rs1299314705; called by muse, mutect2
- TAS2R43 | c.693G>A p.V231= | Silent (SNP) | VAF 88/246 reads (36%) | catalogued as COSV67851518; called by muse, mutect2, varscan2
- TRIM11 | c.1185T>A p.A395= | Silent (SNP) | VAF 34/360 reads (9%) | called by muse, mutect2
- UNC45B | c.120C>A p.A40= | Silent (SNP) | VAF 20/190 reads (11%) | called by muse, varscan2
- UTP6 | c.1677C>G p.P559= | Silent (SNP) | VAF 62/302 reads (21%) | called by muse, varscan2
- VSTM2B | c.306C>A p.R102= | Silent (SNP) | VAF 69/302 reads (23%) | catalogued as COSV100139592; called by muse, mutect2, varscan2
- ABCC8 | c.1332+45C>A | Intron (SNP) | VAF 43/185 reads (23%) | called by muse, mutect2, varscan2
- ADAM6 | n.660G>A | RNA (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2
- AL035425.2 | c.110-47C>T | Intron (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- AR | c.1769-5232C>A | Intron (SNP) | VAF 40/188 reads (21%) | called by mutect2, varscan2
- BIRC2 | c.-1152A>G | 5'UTR (SNP) | VAF 14/85 reads (16%) | catalogued as rs1026597323; called by muse, mutect2, varscan2
- C10orf99 | c.*27C>G | 3'UTR (SNP) | VAF 18/208 reads (9%) | called by muse, mutect2
- C22orf34 | n.70C>A | RNA (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.666+1147G>T | Intron (SNP) | VAF 43/197 reads (22%) | called by muse, mutect2, varscan2
- CDRT15 | c.*9C>T | 3'UTR (SNP) | VAF 16/225 reads (7%) | called by muse, varscan2
- CRELD2 | c.593-279G>A | Intron (SNP) | VAF 40/172 reads (23%) | catalogued as rs1428298845; called by muse, mutect2, varscan2
- CSH1 | c.457-70T>C | Intron (SNP) | VAF 171/850 reads (20%) | catalogued as rs751104762; called by muse, mutect2, varscan2
- DEUP1 | c.*37C>G | 3'UTR (SNP) | VAF 31/166 reads (19%) | catalogued as rs775488544; called by muse, mutect2, varscan2
- FHL2 | chr2:105399076 C>G | 5'Flank (SNP) | VAF 36/133 reads (27%) | called by muse, mutect2, varscan2
- FLJ42393 | n.704T>C | RNA (SNP) | VAF 39/202 reads (19%) | called by muse, mutect2, varscan2
- FLT1 | c.1969+15A>G | Intron (SNP) | VAF 33/193 reads (17%) | called by muse, mutect2, varscan2
- GLRX5 | chr14:95533415 T>A | 5'Flank (SNP) | VAF 63/215 reads (29%) | called by muse, mutect2, varscan2
- HLA-DPB2 | n.36C>A | RNA (SNP) | VAF 89/400 reads (22%) | called by muse, mutect2, varscan2
- LINC01036 | n.235G>A | RNA (SNP) | VAF 87/343 reads (25%) | called by muse, mutect2, varscan2
- LINC01164 | n.763G>C | RNA (SNP) | VAF 27/194 reads (14%) | called by muse, mutect2, varscan2
- MAML3 | c.468+18607_468+18608del | Intron (DEL) | VAF 27/201 reads (13%) | called by mutect2, pindel, varscan2
- MARCHF1 | c.-322-85858G>T | Intron (SNP) | VAF 30/382 reads (8%) | called by muse, mutect2
- MIR124-2 | chr8:64377487 A>C | 5'Flank (SNP) | VAF 44/552 reads (8%) | called by muse, mutect2
- MYH16 | n.4527T>A | RNA (SNP) | VAF 35/223 reads (16%) | called by muse, mutect2, varscan2
- MYLK | c.773+31del | Intron (DEL) | VAF 50/401 reads (12%) | called by mutect2, pindel, varscan2
- NT5C1B | c.1071+74G>A | Intron (SNP) | VAF 85/407 reads (21%) | called by muse, mutect2, varscan2
- OR2P1P | chr6:29076523 G>T | 5'Flank (SNP) | VAF 26/92 reads (28%) | called by muse, mutect2, varscan2
- PLEKHM1P1 | n.927G>T | RNA (SNP) | VAF 44/552 reads (8%) | catalogued as rs750452707; called by muse, mutect2
- PPEF2 | c.1757-119G>T | Intron (SNP) | VAF 20/154 reads (13%) | called by muse, varscan2
- RNF170 | c.*303C>T | 3'UTR (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- SGPL1 | c.615+39dup | Intron (INS) | VAF 8/62 reads (13%) | called by mutect2, pindel, varscan2
- SGSM3 | c.1185+75G>A | Intron (SNP) | VAF 8/54 reads (15%) | catalogued as rs567850727; called by muse, mutect2, varscan2
- SMARCAD1 | c.*190A>G | 3'UTR (SNP) | VAF 26/230 reads (11%) | called by muse, varscan2
- SNORD116-8 | n.91G>C | RNA (SNP) | VAF 39/319 reads (12%) | called by muse, mutect2, varscan2
- SSR4 | c.417+22_417+24del | Intron (DEL) | VAF 23/156 reads (15%) | catalogued as rs782696238; called by pindel, varscan2
- SYK | c.*8C>T | 3'UTR (SNP) | VAF 12/152 reads (8%) | catalogued as rs745620497; called by muse, mutect2
- TGM2 | c.859+176C>G | Intron (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- TPRXL | n.1059G>C | RNA (SNP) | VAF 42/209 reads (20%) | called by muse, mutect2, varscan2
- TRPM2 | c.3462-1292G>T | Intron (SNP) | VAF 100/273 reads (37%) | called by muse, mutect2, varscan2
- UNC13D | c.951+11C>G | Intron (SNP) | VAF 28/283 reads (10%) | called by muse, mutect2, varscan2
- UNKL | chr16:1414735 C>A | 5'Flank (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- WAC | c.42-54G>A | Intron (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
- WDR49 | c.-65-15976G>A | Intron (SNP) | VAF 25/122 reads (20%) | catalogued as rs1309167258; called by muse, mutect2, varscan2
- WEE1 | c.1141+648G>A | Intron (SNP) | VAF 62/329 reads (19%) | called by muse, mutect2, varscan2
- ZEB1 | c.-48G>T | 5'UTR (SNP) | VAF 30/312 reads (10%) | called by muse, mutect2
- ZNF385D | c.-19G>C | 5'UTR (SNP) | VAF 50/322 reads (16%) | catalogued as COSV99873877, COSV99876197; called by muse, mutect2, varscan2
- ZNF578 | chr19:52451394 G>T | 5'Flank (SNP) | VAF 15/72 reads (21%) | catalogued as COSV56520754; called by muse, mutect2
- ZNF98 | c.-1G>T | 5'UTR (SNP) | VAF 43/348 reads (12%) | called by muse, mutect2, varscan2
